Gene-level copy-number profile of tumor specimen ALCH-B3DG-TTP1-A from ALCHEMIST case ALCH-B3DG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 81.0 years (29,569 days).
Specimen ALCH-B3DG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 072b6d0c-a9ea-45ad-bf68-e14ec67b342c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/baf4fe12-35e5-4479-9a0a-ba8c87c8bb01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,812; copy number 2: 55,882; copy number 3: 143; copy number 4: 3; copy number 5: 11; copy number 7: 2; copy number 8: 1; copy number 10: 1; copy number 13: 5; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,491,160–131,491,236, 1 gene (within-gene range 0–2): MIR4784.
- chr7:5,306,790–5,425,414, 1 gene (within-gene range 0–2): TNRC18.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr22:21,938,269–21,977,632, 1 gene (within-gene range 0–2): PPM1F-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,817,870–64,836,341, 1 gene, copy number 10: AL359955.1.
- chr10:63,110,139–63,655,769, 13 genes, copy number 5–16: RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–7 (within-gene range 1–7): PWP2, GATD3A.
- chr22:15,282,557–15,350,043, 5 genes, copy number 13: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 65. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
